FM case AD6701 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/2fb5e38a-6b65-43ae-945c-9fa8109b2de5

Male, 50.0 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the rectum; primary biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
